Somatic mutation profile of tumor specimen TCGA-N5-A4RF-01A (aliquot TCGA-N5-A4RF-01A-11D-A28R-08) from TCGA case TCGA-N5-A4RF, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Age at diagnosis: 68.6 years (25,041 days).
Specimen TCGA-N5-A4RF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df10c308-a9c8-4aa5-a8d9-0d5917a1a807.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N5-A4RF-10A (Blood Derived Normal), aliquot TCGA-N5-A4RF-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d03f78d-a62b-44d4-b099-7efb910b946c

The open-access MAF lists 83 somatic variants for this specimen: 68 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 14, Nonsense Mutation 6, Splice Site 2, Frame Shift Ins 2, Frame Shift Del 2, Nonstop Mutation 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 13/14 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 35/46 reads (76%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519930, COSV55874291, COSV55888676, COSV55926774; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PPP2R1A | c.767C>A p.S256Y | Missense Mutation (SNP) | VAF 14/51 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59042523, COSV59042723; called by muse, mutect2, varscan2
- PTEN | c.1026+2T>G p.X342_splice | Splice Site (SNP) | VAF 8/47 reads (17%) | hotspot (GDC flag); catalogued as rs1114167624, COSV100910531, COSV64291630; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 43/52 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADCY9 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.332); catalogued as rs755610495; called by muse, mutect2, varscan2
- ALCAM | c.818A>G p.N273S | Missense Mutation (SNP) | VAF 39/47 reads (83%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as rs778223241; called by muse, mutect2, varscan2
- ARID1A | c.1602C>G p.Y534* | Nonsense Mutation (SNP) | VAF 237/562 reads (42%) | catalogued as COSV100254007, COSV61377796; called by muse, mutect2, varscan2
- CD247 | c.490C>T p.R164C (on ENST00000362089 / NM_198053.3; = p.R163C on NM_000734.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs752198795; called by muse, mutect2, varscan2
- DDX51 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as rs370006300; called by muse, mutect2, varscan2
- DLG3 | c.1490G>A p.R497Q (on ENST00000374360 / NM_021120.4; = p.R160Q on NM_020730.3) | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as rs987095691; called by muse, mutect2, varscan2
- DMD | c.6194G>T p.S2065I | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.301); catalogued as rs767872954; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EFHC1 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as rs758695181; called by muse, mutect2, varscan2
- ESF1 | c.412A>T p.K138* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV52521234; called by muse, mutect2
- FXYD5 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779297539, COSV61569465; called by muse, mutect2, varscan2
- GPAM | c.832C>T p.R278* | Nonsense Mutation (SNP) | VAF 33/50 reads (66%) | catalogued as rs750976067, COSV62080700; called by muse, mutect2, varscan2
- GRIA1 | c.2209G>A p.V737M | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53604553; called by muse, mutect2, varscan2
- KCND3 | c.1678T>C p.S560P | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.049); catalogued as COSV56179182; called by muse, mutect2, varscan2
- KMT2B | c.5458C>T p.P1820S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1568379896; called by muse, mutect2, varscan2
- KRTAP24-1 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs774705764, COSV61089169, COSV61090157; called by muse, mutect2, varscan2
- MOCS1 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs746138504; called by muse, mutect2, varscan2
- NOB1 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs373158111; called by muse, mutect2, varscan2
- NPLOC4 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 59/80 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs373063460; called by muse, mutect2, varscan2
- NUP205 | c.5299C>T p.L1767F | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs1214349650; called by muse, mutect2, varscan2
- PCDHA7 | c.2159C>T p.A720V | Missense Mutation (SNP) | VAF 71/117 reads (61%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.021); catalogued as rs1554136059, COSV65337511; called by muse, mutect2, varscan2
- PLEC | c.4751G>A p.R1584Q (on ENST00000322810 / NM_201380.4; = p.R1474Q on NM_000445.5) | Missense Mutation (SNP) | VAF 27/30 reads (90%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as rs375600751; called by muse, mutect2, varscan2
- RBBP7 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 152/248 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV58112620; called by muse, mutect2, varscan2
- ROBO2 | c.790G>C p.D264H | Missense Mutation (SNP) | VAF 46/52 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59922140; called by muse, mutect2, varscan2
- RSPH6A | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs778938225; called by muse, mutect2, varscan2
- SCGB1D2 | c.54G>T p.Q18H | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV99793585; called by muse, mutect2, varscan2
- SEMA5A | c.2737G>A p.V913I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs545915512, COSV66795965; called by muse, mutect2, varscan2
- SEMA5A | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as rs368799668; called by muse, mutect2, varscan2
- SLC1A6 | c.1093G>A p.V365I | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1364120285, COSV55667975, COSV55672668; called by muse, mutect2, varscan2
- SPATA31A1 | c.3689C>T p.S1230L | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1400895751; called by muse, mutect2
- SV2B | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 20/33 reads (61%) | catalogued as rs767247777, COSV57700498; called by muse, mutect2, varscan2
- TBX1 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.576); catalogued as rs777394492; called by muse, mutect2, varscan2
- TRMT61B | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs755865287; called by muse, mutect2
- TTC12 | c.1337C>T p.S446L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as rs147647661; called by muse, mutect2, varscan2
- TTC21A | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 31/35 reads (89%) | catalogued as COSV57182868; called by muse, mutect2, varscan2
- VPS26C | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.188); catalogued as rs929188939; called by muse, mutect2, varscan2
- WNK1 | c.2003G>A p.R668Q | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT tolerated (0.44); PolyPhen benign (0.114); catalogued as rs753167766; called by muse, mutect2, varscan2
- ZNF444 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1420566700; called by muse, mutect2, varscan2
- ZNF700 | c.1211C>A p.S404Y | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as COSV54315279; called by muse, mutect2, varscan2
- ZSWIM2 | c.724A>G p.I242V | Missense Mutation (SNP) | VAF 73/92 reads (79%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.602); catalogued as rs908428997; called by muse, mutect2, varscan2
- ARID1A | c.6855_*8del | Nonstop Mutation (DEL) | VAF 22/58 reads (38%) | called by mutect2, pindel, varscan2
- CHD4 | c.3296T>C p.F1099S (on ENST00000357008 / NM_001363606.2; = p.F1112S on NM_001273.5) | Missense Mutation (SNP) | VAF 47/64 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CMYA5 | c.895G>T p.V299F | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTCF | c.378_381del p.A127Pfs*4 | Frame Shift Del (DEL) | VAF 35/81 reads (43%) | called by mutect2, pindel, varscan2
- DARS2 | c.1064T>G p.F355C | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- ELAVL2 | c.75T>G p.C25W | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.447); called by muse, mutect2
- EP300 | c.51dup p.L18Tfs*21 | Frame Shift Ins (INS) | VAF 66/193 reads (34%) | called by mutect2, pindel, varscan2
- GAS8 | c.89A>G p.Q30R | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- HLF | c.574A>C p.M192L | Missense Mutation (SNP) | VAF 54/79 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KMT2B | c.5222G>A p.G1741D | Missense Mutation (SNP) | VAF 134/306 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCF2 | c.11C>G p.A4G | Missense Mutation (SNP) | VAF 99/224 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PCDHB13 | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- PDE7B | c.83-7_100del p.X28_splice | Splice Site (DEL) | VAF 12/122 reads (10%) | called by mutect2, pindel
- PDK2 | c.627G>C p.K209N | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- PDK3 | c.1036T>A p.S346T | Missense Mutation (SNP) | VAF 82/207 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PTEN | c.906_919del p.S302Rfs*5 | Frame Shift Del (DEL) | VAF 22/44 reads (50%) | called by pindel, varscan2*
- RB1 | c.2175_2183del p.T726_Y728del | In Frame Del (DEL) | VAF 34/40 reads (85%) | called by mutect2, pindel, varscan2
- RELN | c.2033G>T p.C678F | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SYNE1 | c.8649dup p.K2884* (on ENST00000367255 / NM_182961.4; = p.K2891* on NM_033071.3) | Frame Shift Ins (INS) | VAF 23/71 reads (32%) | called by mutect2, pindel, varscan2
- TBC1D3L | c.975C>A p.C325* | Nonsense Mutation (SNP) | VAF 10/12 reads (83%) | called by mutect2, varscan2
- TNIK | c.3019C>A p.L1007I | Missense Mutation (SNP) | VAF 74/91 reads (81%) | SIFT tolerated (0.4); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- TRMT10A | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- ZNF493 | c.752G>A p.C251Y | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF676 | c.415A>T p.T139S (on ENST00000650058; = p.T107S on NM_001001411.3) | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- ADCY2 | c.1797G>A p.A599= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as rs778398128, COSV57859762; called by muse, mutect2, varscan2
- FAM71A | c.375G>A p.R125= | Silent (SNP) | VAF 19/130 reads (15%) | catalogued as rs766628483; called by muse, mutect2, varscan2
- FLNA | c.5916C>A p.P1972= (on ENST00000369850 / NM_001110556.2; = p.P1964= on NM_001456.3) | Silent (SNP) | VAF 42/133 reads (32%) | called by muse, mutect2, varscan2
- HSPA2 | c.525C>T p.N175= | Silent (SNP) | VAF 53/141 reads (38%) | called by muse, mutect2, varscan2
- ICA1 | c.492G>A p.T164= | Silent (SNP) | VAF 42/118 reads (36%) | catalogued as COSV104377038, COSV99655591; called by muse, mutect2, varscan2
- IRS4 | c.3450C>T p.A1150= | Silent (SNP) | VAF 28/206 reads (14%) | catalogued as COSV64532512; called by muse, mutect2, varscan2
- NAT16 | c.984C>T p.N328= | Silent (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- PCDHA2 | c.2058C>T p.A686= | Silent (SNP) | VAF 70/191 reads (37%) | called by muse, mutect2, varscan2
- RAB39B | c.435C>T p.Y145= | Silent (SNP) | VAF 55/121 reads (45%) | catalogued as rs376181426, COSV65624655; called by muse, mutect2, varscan2
- RGS7 | c.369G>A p.P123= | Silent (SNP) | VAF 122/165 reads (74%) | catalogued as rs749423672; called by muse, mutect2, varscan2
- RIMS1 | c.1536C>A p.S512= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV53482892; called by muse, mutect2, varscan2
- TAFA5 | c.51C>T p.P17= | Silent (SNP) | VAF 2/10 reads (20%) | called by muse, mutect2
- TENM1 | c.5283C>T p.P1761= | Silent (SNP) | VAF 43/122 reads (35%) | catalogued as rs767488809; called by muse, mutect2, varscan2
- TSR1 | c.1956G>A p.A652= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs762088662; called by muse, mutect2, varscan2
- SSPOP | n.13016G>A | RNA (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
